Somatic mutation profile of tumor specimen TCGA-S9-A7R8-01A (aliquot TCGA-S9-A7R8-01A-11D-A34J-08) from TCGA case TCGA-S9-A7R8, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 44.6 years (16,275 days).
Specimen TCGA-S9-A7R8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3c57958-0c5b-4ea9-8e78-4b1f7ff7e085.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A7R8-10A (Blood Derived Normal), aliquot TCGA-S9-A7R8-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51fe62f9-77a2-481b-9912-8a4de10b90de

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 8, Nonsense Mutation 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 44/123 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- JAK3 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761583890, COSV71686909; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MMAB | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398124434, CM061117, COSV57169694, COSV57169996; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 31/34 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ATRX | c.2417del p.K806Rfs*16 | Frame Shift Del (DEL) | VAF 145/395 reads (37%) | catalogued as COSV100970906; called by pindel, varscan2
- ATRX | c.2404A>G p.I802V | Missense Mutation (SNP) | VAF 198/398 reads (50%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1431937285, COSV100971337; called by muse, varscan2
- CEP55 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs767877691, COSV65184770; called by muse, mutect2, varscan2
- CHGB | c.2030G>A p.G677D | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568552867, COSV100973077, COSV66760327; called by muse, varscan2
- CIAO2A | c.129G>C p.L43F | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.121); catalogued as COSV100256695; called by muse, mutect2, varscan2
- CNGA4 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1437010296, COSV66005824; called by muse, mutect2
- CSF2RA | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.442); catalogued as rs201377602, COSV62626309; called by muse, mutect2, varscan2
- DCAF12L2 | c.1358G>A p.G453D | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV100758803; called by muse, mutect2, varscan2
- DNAH17 | c.5920G>A p.V1974I | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as rs374326783; called by muse, mutect2
- ERAS | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV54433301; called by muse, mutect2, varscan2
- FFAR2 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 237/330 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs774785188, COSV55832795; called by muse, mutect2, varscan2
- FZD1 | c.1406A>G p.D469G | Missense Mutation (SNP) | VAF 75/191 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99842717; called by muse, mutect2, varscan2
- GALNT5 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs371955379; called by muse, mutect2, varscan2
- KIF13B | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101580788; called by muse, mutect2
- MAPK15 | c.878T>G p.L293* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100568064; called by muse, mutect2, varscan2
- NLRP5 | c.2851C>T p.R951W | Missense Mutation (SNP) | VAF 49/66 reads (74%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); catalogued as rs778188316, COSV66764200; called by muse, mutect2, varscan2
- OR6Y1 | c.656T>C p.V219A | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV100225480; called by muse, mutect2, varscan2
- RASEF | c.2055A>C p.L685F | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100907043; called by muse, mutect2, varscan2
- RBL1 | c.1673T>C p.I558T | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as rs756500759, COSV100727275; called by muse, mutect2, varscan2
- SEMA3A | c.102A>C p.L34F | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as COSV99547822; called by muse, mutect2, varscan2
- SLAMF9 | c.626T>C p.V209A | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV63636401; called by muse, mutect2, varscan2
- TPST1 | c.471T>A p.C157* | Nonsense Mutation (SNP) | VAF 46/83 reads (55%) | catalogued as COSV100507326; called by muse, mutect2, varscan2
- ADCY3 | c.528C>T p.V176= | Silent (SNP) | VAF 39/73 reads (53%) | catalogued as COSV99569021; called by muse, mutect2, varscan2
- C3 | c.4917C>T p.D1639= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as rs780269222, COSV99837160; called by muse, mutect2
- FAM24A | c.6A>G p.A2= | Silent (SNP) | VAF 85/199 reads (43%) | catalogued as COSV100925087; called by muse, mutect2, varscan2
- LTB4R | c.573G>T p.L191= | Silent (SNP) | VAF 90/139 reads (65%) | catalogued as COSV99351041, COSV99351124; called by muse, mutect2, varscan2
- NOMO2 | c.729T>G p.T243= | Silent (SNP) | VAF 57/168 reads (34%) | catalogued as COSV100395797; called by muse, mutect2, varscan2
- NOP53 | c.165G>A p.P55= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1322029752, COSV54406766; called by muse, mutect2, varscan2
- RASAL2 | c.2340G>A p.S780= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as rs755892625, COSV100862865; called by muse, mutect2, varscan2
- TKT | c.966G>A p.G322= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs1553676807, COSV99965142; called by muse, mutect2, varscan2
- PPP1R9A | c.2757+572C>T | Intron (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
